Surgical pathology report (de-identified scan), TCGA case TCGA-AW-A1PO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Cureline, specimen TCGA-AW-A1PO-01A (Primary Tumor).

Project #
TSS #

1CD-0-3
Adenocarcinoma, Endometrial, NIS
Site: Endometrium C54.1 3/12/11 *lv* 8380/3

Index	Specimen label	Clinical Site #	Case #	Ethnicity (Race)	Clinical Diagnosis	DOB (mm/dd/yyyy)	Sex	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format
1				Caucasian (White) Caucasian (White)	Endometrial cancer Endometrial cancer		Female Female		Uterus Blood	Primary n/a	Tumor normal	Tissue Blood	Frozen Frozen
Container	Number of containers	Amount/per container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Prior Chemo / Hormonal Th	Chemo / Horm Th Details	Prior Radiation	Cellular Tumor %
cryomold	1	230	mg	Surgery	Endometroid Adenocarcinoma	3	1	0	0	no	no	no	90
tube	1	4	ml	Blood draw	n/a	n/a	n/a	n/a	n/a	no	no	no	n/a

Check	Yes	No
HPV A Discrepancy		
Prior Metastasis History		
Dual/Sync/Endo Primary Status		

Source: NCI Genomic Data Commons file 6b0b7c38-86c0-4a7e-857a-96d07f53dbf3 (TCGA-AW-A1PO.B5351001-32B2-4BA9-998D-F6631F6BE705.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).